Somatic mutation profile of cancer-model specimen HCM-BROD-0199-C71-85A (Adherent Cell Line, passage 9; aliquot HCM-BROD-0199-C71-85A-01D-A786-36), derived from the primary tumor of HCMI case HCM-BROD-0199-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.1 years (17,924 days).
Specimen HCM-BROD-0199-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afc1adab-50b5-4b1e-b76a-008ab5c6ce50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0199-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0199-C71-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25a7c47d-a72d-4b64-b961-15776d97d3f6

The open-access MAF lists 63 somatic variants for this specimen: 40 protein-altering or splice-affecting, 18 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 18, Nonsense Mutation 4, 3'Flank 2, 3'UTR 2, 5'UTR 1, Frame Shift Ins 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1C | c.959C>T p.T320M | Missense Mutation (SNP) | VAF 178/389 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs377737331; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD163L1 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 118/334 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs139153315; called by muse, mutect2, varscan2
- CD209 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 117/276 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs139712001; called by muse, mutect2, varscan2
- DAAM2 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 11/254 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs898550504, COSV51365030; called by muse, mutect2
- DNAH7 | c.7108G>A p.G2370R | Missense Mutation (SNP) | VAF 33/238 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.315); catalogued as rs778309177; called by muse, mutect2, varscan2
- DNAI1 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 266/587 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs752354598, COSV54280364, COSV54280621; called by muse, mutect2, varscan2
- DROSHA | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 144/311 reads (46%) | catalogued as COSV60781622; called by muse, mutect2, varscan2
- ESPNL | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 179/395 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs778024556, COSV54541083; called by muse, mutect2, varscan2
- GRB7 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.532); catalogued as rs201668668; called by muse, mutect2
- GRIP1 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 245/561 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs367635870; called by muse, mutect2, varscan2
- GUCY1B1 | c.1823dup p.N608Kfs*11 | Frame Shift Ins (INS) | VAF 100/259 reads (39%) | catalogued as rs757993339; called by mutect2, pindel, varscan2
- HMCN1 | c.10904G>A p.R3635Q | Missense Mutation (SNP) | VAF 229/517 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as rs777872545, COSV54908505; called by muse, mutect2, varscan2
- INTS2 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.42); catalogued as rs1336198754; called by muse, mutect2, varscan2
- LETM1 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 167/332 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201510306, COSV57103367; called by muse, mutect2, varscan2
- NLRP3 | c.1666G>A p.V556M | Missense Mutation (SNP) | VAF 477/997 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.161); catalogued as rs199637520; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRROS | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 188/374 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs986757744; called by muse, mutect2, varscan2
- PPP3R2 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 204/399 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs1200972717, COSV62455332; called by muse, mutect2, varscan2
- PTEN | c.183T>G p.H61Q | Missense Mutation (SNP) | VAF 40/40 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64289119, COSV99057944; called by muse, mutect2, varscan2
- REPS2 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 65/65 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58184927; called by muse, mutect2, varscan2
- TSKS | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.859); catalogued as rs1317673712; called by muse, mutect2
- TTC28 | c.2143C>T p.R715* | Nonsense Mutation (SNP) | VAF 126/256 reads (49%) | catalogued as COSV67414832; called by muse, mutect2, varscan2
- UBR4 | c.3617C>G p.S1206C | Missense Mutation (SNP) | VAF 163/358 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs555728639, COSV64382807; called by muse, mutect2, varscan2
- ZNF333 | c.1295C>T p.T432M | Missense Mutation (SNP) | VAF 144/323 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1240772288; called by muse, mutect2, varscan2
- ZNF831 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 100/253 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64040754; called by muse, mutect2, varscan2
- ANKS1A | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD6 | c.4069G>T p.E1357* | Nonsense Mutation (SNP) | VAF 149/347 reads (43%) | called by muse, mutect2, varscan2
- CPA6 | c.293T>G p.L98* | Nonsense Mutation (SNP) | VAF 40/92 reads (43%) | called by muse, mutect2, varscan2
- DGKI | c.956T>G p.V319G | Missense Mutation (SNP) | VAF 90/424 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- DPP4 | c.211A>G p.K71E | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EPHA8 | c.2252T>A p.L751H | Missense Mutation (SNP) | VAF 251/598 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FLNC | c.6813C>A p.D2271E | Missense Mutation (SNP) | VAF 60/1248 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- GRM6 | c.320A>C p.E107A | Missense Mutation (SNP) | VAF 98/219 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- NPAS3 | c.2289_2294del p.G771_G772del (on ENST00000356141 / NM_001164749.2; = p.G739_G740del on NM_022123.3) | In Frame Del (DEL) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- POLR2A | c.4174T>C p.Y1392H | Missense Mutation (SNP) | VAF 211/461 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- RTBDN | c.543C>G p.C181W (on ENST00000393233 / NM_001270444.1; = p.C213W on NM_031429.2) | Missense Mutation (SNP) | VAF 100/213 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SSC4D | c.371A>G p.N124S | Missense Mutation (SNP) | VAF 47/279 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- VPS13D | c.12159C>A p.F4053L | Missense Mutation (SNP) | VAF 83/174 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- ZAP70 | c.41G>T p.S14I | Missense Mutation (SNP) | VAF 183/375 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZNF462 | c.6174_6175del p.C2059Lfs*7 | Frame Shift Del (DEL) | VAF 99/327 reads (30%) | called by pindel, varscan2
- ZNF708 | c.1640T>G p.L547R | Missense Mutation (SNP) | VAF 154/306 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CILP | c.1767G>A p.L589= | Silent (SNP) | VAF 161/324 reads (50%) | catalogued as COSV99973097; called by muse, mutect2, varscan2
- FLNC | c.5433G>A p.R1811= | Silent (SNP) | VAF 291/1211 reads (24%) | called by muse, mutect2, varscan2
- IGF1 | c.108G>A p.A36= | Silent (SNP) | VAF 218/442 reads (49%) | catalogued as rs371125874; called by muse, mutect2, varscan2
- MAP3K20 | c.1908G>A p.S636= | Silent (SNP) | VAF 165/342 reads (48%) | catalogued as rs112889653; called by mutect2, varscan2
- NCAM2 | c.1134T>C p.Y378= | Silent (SNP) | VAF 80/212 reads (38%) | called by muse, mutect2, varscan2
- OBSCN | c.21444G>A p.A7148= | Silent (SNP) | VAF 127/220 reads (58%) | catalogued as rs375088814; called by muse, mutect2, varscan2
- OR2AT4 | c.213C>A p.L71= | Silent (SNP) | VAF 20/406 reads (5%) | catalogued as COSV59406296; called by muse, mutect2
- PIK3C2G | c.2868C>T p.N956= (on ENST00000676171; = p.N915= on NM_004570.5) | Silent (SNP) | VAF 74/211 reads (35%) | called by muse, mutect2, varscan2
- RNF151 | c.360G>A p.S120= | Silent (SNP) | VAF 182/414 reads (44%) | catalogued as rs374940392, COSV58400005; called by muse, mutect2, varscan2
- RRP1 | c.807C>T p.P269= | Silent (SNP) | VAF 64/119 reads (54%) | catalogued as rs774930391, COSV101513845, COSV101513866; called by muse, mutect2, varscan2
- SCUBE2 | c.855G>A p.T285= | Silent (SNP) | VAF 92/188 reads (49%) | catalogued as rs553227629; called by muse, mutect2, varscan2
- SEMA3C | c.720G>T p.V240= | Silent (SNP) | VAF 54/292 reads (18%) | called by muse, mutect2, varscan2
- SOCS4 | c.225G>A p.E75= | Silent (SNP) | VAF 162/346 reads (47%) | called by muse, mutect2, varscan2
- SPOCD1 | c.867C>T p.P289= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as rs370591004, COSV57100233; called by muse, mutect2, varscan2
- TAF3 | c.2118G>A p.K706= | Silent (SNP) | VAF 12/12 reads (100%) | called by muse, mutect2, varscan2
- TGM7 | c.732C>T p.G244= | Silent (SNP) | VAF 163/293 reads (56%) | catalogued as rs765744133; called by muse, mutect2, varscan2
- TM6SF2 | c.600C>T p.T200= | Silent (SNP) | VAF 67/139 reads (48%) | catalogued as rs748636134; called by muse, mutect2, varscan2
- ZSWIM4 | c.231G>A p.R77= | Silent (SNP) | VAF 248/516 reads (48%) | catalogued as rs1203070982, COSV99584488; called by muse, mutect2, varscan2
- AC010507.1 | chr19:200767 C>T | 3'Flank (SNP) | VAF 4/294 reads (1%) | catalogued as rs752589210; called by muse, mutect2
- CPLX2 | c.*134G>C | 3'UTR (SNP) | VAF 96/186 reads (52%) | called by muse, mutect2, varscan2
- GNE | c.*1049C>T | 3'UTR (SNP) | VAF 41/41 reads (100%) | called by muse, mutect2, varscan2
- PGAM5P1 | chr5:109883954 G>A | 3'Flank (SNP) | VAF 13/331 reads (4%) | catalogued as rs997840234; called by muse, mutect2
- TMEM37 | c.-46G>A | 5'UTR (SNP) | VAF 21/36 reads (58%) | called by muse, mutect2, varscan2
